CMI case PCProject_0130 — CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/98b3bb3e-99a2-48ec-8069-1928e304a06f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, NOS: Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Age at diagnosis: 59.9 years (21,888 days).

Biospecimens (3 samples)
- Sample PCProject_0130_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Prostate.
- Samples PCProject_0130_T1_RNA, PCProject_0130_T1_WES (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
